CCDI case PBCNFR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/44e295e2-6226-4026-9a29-95da17d9ddaf

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.8 years (5,398 days).

Biospecimens (3 samples)
- Sample 0DVZ0N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVZ0Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVZ17: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
